Somatic mutation profile of tumor specimen ALCH-B45V-TTP1-A (aliquot ALCH-B45V-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B45V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.6 years (25,420 days).
Specimen ALCH-B45V-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8df0b44-9f80-40e8-a20a-86d9ddb903be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B45V-NB1-A (Blood Derived Normal), aliquot ALCH-B45V-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/447bb106-2b12-4cd7-a902-9ac721fbda0c

The open-access MAF lists 33 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, Frame Shift Ins 2, 5'UTR 1, Frame Shift Del 1, Splice Region 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 71/323 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRPF3 | c.2705A>G p.N902S | Missense Mutation (SNP) | VAF 57/312 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs572446431, COSV60206116; called by muse, mutect2, varscan2
- CCT3 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs199557682, COSV55290355; called by muse, mutect2
- EXOC3L2 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 62/285 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.096); catalogued as rs763701800; called by muse, mutect2, varscan2
- F13A1 | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 51/378 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs184352526; called by muse, mutect2, varscan2
- FAT4 | c.13957A>G p.I4653V | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.811); catalogued as rs748401687, COSV58705250; called by muse, mutect2, varscan2
- KLRG1 | c.251A>T p.N84I | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as rs1373791992; called by muse, mutect2, varscan2
- MAP2K7 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as rs776342808; called by muse, mutect2, varscan2
- NRG1 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.013); catalogued as COSV55155703, COSV55172943; called by muse, mutect2
- PRAM1 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.555); catalogued as rs1166359141, COSV99725916; called by muse, mutect2, varscan2
- PTPRS | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.523); catalogued as rs1383575470, COSV53619678; called by muse, mutect2, varscan2
- STOM | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as rs1330446908, COSV99713554; called by muse, mutect2, varscan2
- ABCF3 | c.1392-5C>T | Splice Region (SNP) | VAF 38/231 reads (16%) | called by muse, mutect2, varscan2
- ADAM18 | c.2130A>C p.R710S | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- BCO2 | c.1494T>G p.D498E | Missense Mutation (SNP) | VAF 82/424 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL27A1 | c.1589C>T p.P530L | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DMXL1 | c.391T>A p.Y131N | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELF3 | c.782dup p.E262Rfs*39 | Frame Shift Ins (INS) | VAF 22/128 reads (17%) | called by mutect2, pindel, varscan2
- ICAM5 | c.350T>C p.F117S | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- MPHOSPH9 | c.2772_2773insTT p.P925Ffs*53 | Frame Shift Ins (INS) | VAF 38/196 reads (19%) | called by mutect2, pindel, varscan2
- NOL9 | c.776del p.L259* | Frame Shift Del (DEL) | VAF 23/202 reads (11%) | called by mutect2, pindel, varscan2
- SLC25A45 | c.844T>G p.Y282D | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.102); called by muse, mutect2
- ZNF646 | c.4511A>T p.Q1504L | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASCC3 | c.2433G>T p.T811= | Silent (SNP) | VAF 32/172 reads (19%) | called by muse, mutect2, varscan2
- ATG7 | c.37C>T p.L13= | Silent (SNP) | VAF 44/272 reads (16%) | catalogued as rs200350728; called by muse, mutect2, varscan2
- ATP2A1 | c.399C>T p.D133= | Silent (SNP) | VAF 75/440 reads (17%) | called by muse, mutect2, varscan2
- ATR | c.5391T>C p.S1797= | Silent (SNP) | VAF 38/223 reads (17%) | called by muse, mutect2, varscan2
- FAM47B | c.1038A>G p.L346= | Silent (SNP) | VAF 63/350 reads (18%) | called by muse, mutect2, varscan2
- PLCB3 | c.495C>T p.N165= | Silent (SNP) | VAF 32/198 reads (16%) | called by muse, mutect2
- PPP1R13L | c.51C>T p.F17= | Silent (SNP) | VAF 38/181 reads (21%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505159 C>T | 5'Flank (SNP) | VAF 28/193 reads (15%) | catalogued as rs780525347; called by muse, mutect2, varscan2
- CALU | c.415+217G>A | Intron (SNP) | VAF 18/158 reads (11%) | called by muse, mutect2
- DVL1 | c.-21G>C | 5'UTR (SNP) | VAF 16/93 reads (17%) | called by muse, mutect2
